Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAHM, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAHM-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 9.0 cm; no angio-invasion; no invasion of rete testis; no invasion of tunica albuginea; epididymis and spermatic cord not present in the available slides.

Date of procurement (= date of orchidectomy):

ICD-0-3

Seminoma NOS 9061/3
Site (R) Testis NOS 662.9
W 3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file dbd6cc6d-8b36-4848-88e5-3f9ed8e00176 (TCGA-2G-AAHM-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).